Somatic mutation profile of tumor specimen C3L-04764-54 (aliquot CPT0260550002) from CPTAC case C3L-04764, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 78.9 years (28,831 days).
Specimen C3L-04764-54: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 17945034-2a19-47ad-9a4a-27037598be18.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-04764-50 (Buccal Cell Normal), aliquot CPT0260540003; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/72a2c69b-9b6e-4d3b-a08b-6cf4f2f50a92

The open-access MAF lists 7 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Silent 1, Intron 1, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SHROOM3 | c.3908G>A p.G1303D | Missense Mutation (SNP) | VAF 83/172 reads (48%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.949); catalogued as rs1353270199; called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.2011C>T p.R671* (on ENST00000540229 / NM_001371097.1; = p.R610* on NM_001009562.4) | Nonsense Mutation (SNP) | VAF 50/103 reads (49%) | catalogued as rs1426459557, COSV67441338; called by muse, mutect2, varscan2
- LIN28B | c.50T>C p.L17P | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- MN1 | c.3884_3890del p.R1295Pfs*23 | Frame Shift Del (DEL) | VAF 34/178 reads (19%) | called by mutect2, varscan2
- ZNF732 | c.802C>T p.H268Y | Missense Mutation (SNP) | VAF 64/133 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.417); called by muse, mutect2, varscan2
- ITGA10 | c.1713G>A p.A571= | Silent (SNP) | VAF 193/405 reads (48%) | catalogued as rs782328114, COSV65197625; called by muse, mutect2, varscan2
- POLM | c.1399-31C>T | Intron (SNP) | VAF 31/37 reads (84%) | called by muse, mutect2, varscan2
